Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A85J, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A85J-01A (Primary Tumor).

TSS Patient ID:

Surgical Date:

Gross Description: There is a skin flap with a black node on the broad base, up to 4 x 3.5 cm in its size, up to 1 cm thick. Separately there is a resection margin.

Microscopic Description: Malignant melanoma of the skin without superficial ulceration. Breslow tumor thickness is 5.5 mm. In the resection margin there is fibrous, fatty and bone tissue.

Diagnosis Details: Tumor Features: Pigmented, Tumor Extent: More than 4 mm with or without ulceration, Venous Invasion: Absent, Margins: Absent, Treatment Effect:

ICD O-3

Comments:

Formatted Path Reports: SKIN TISSUE CHECKLIST

Melanoma, malignant NOS
Site Skin of hip
8720/3
044-7
JW 4/14/14

Specimen type: Excision of skin lesion

Tumor site: Skin, hip

Tumor size: 3.5 x 0.55 x 4 cm

Tumor features: Pigmented

Satellite nodules: Not specified

Histologic type: Malignant melanoma

Histologic grade: Not specified

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: No

Additional pathologic findings: Breslow tumor thickness is 5.5 mm.

Comments: None

PAA Discrepancy		
For Malignancy History		
Is (circle):		
Viewer Initials		

10/24/13
10/24/13

Source: NCI Genomic Data Commons file 7c3317fa-d18e-4ab8-8d4e-d1567f4d35bb (TCGA-EB-A85J.AD298262-1D6D-4023-9DBA-A38A8ED1E3EB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).